Somatic mutation profile of tumor specimen TCGA-3S-A8YW-01A (aliquot TCGA-3S-A8YW-01A-11D-A423-09) from TCGA case TCGA-3S-A8YW, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 63.1 years (23,053 days).
Specimen TCGA-3S-A8YW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3802145e-257b-4c4f-8471-d27bb9960317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3S-A8YW-10A (Blood Derived Normal), aliquot TCGA-3S-A8YW-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c0c84a1-0c7f-4084-9160-2c90eba90993

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 19, Silent 15, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | catalogued as rs587782206; called by pindel, varscan2
- DIPK1B | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs752676384; called by muse, mutect2, varscan2
- GALNTL6 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs748563766; called by muse, mutect2, varscan2
- KIF18A | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs151125849; called by muse, mutect2, varscan2
- MAD2L1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.985); catalogued as rs767071365; called by muse, mutect2, varscan2
- NTF3 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs973177029, COSV58418189; called by muse, mutect2, varscan2
- REV3L | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs547946785; called by muse, mutect2, varscan2
- TBX18 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs987207695, COSV63736139, COSV63737235; called by muse, mutect2, varscan2
- TEX14 | c.2899G>A p.A967T (on ENST00000240361 / NM_001201457.2; = p.A961T on NM_031272.5) | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99541887; called by muse, mutect2, varscan2
- TP53 | c.842del p.D281Afs*64 | Frame Shift Del (DEL) | VAF 35/52 reads (67%) | catalogued as CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; called by mutect2, pindel, varscan2
- DMD | c.6441A>C p.E2147D | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DNAH10 | c.11381T>A p.I3794N (on ENST00000409039; = p.I3733N on NM_207437.3) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DSG3 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.04); called by muse, mutect2
- ESF1 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GET4 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GRIN2B | c.4412G>C p.G1471A | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.779); called by muse, mutect2
- MPP6 | c.1622G>C p.*541Sext*1 | Nonstop Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- RSPH10B | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TNR | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TOGARAM1 | c.1952G>T p.S651I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPCN1 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS13B | c.2978G>C p.R993T | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ACTN3 | c.1482C>T p.C494= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs375736866; called by muse, mutect2, varscan2
- ARMC4 | c.1515C>T p.T505= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs369884669, COSV100537474; called by muse, mutect2, varscan2
- CCDC51 | c.807G>C p.L269= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- EFHC1 | c.1537T>C p.L513= | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- ERBB2 | c.2619C>T p.D873= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs540921632; called by muse, mutect2, varscan2
- ERP44 | c.330C>A p.L110= | Silent (SNP) | VAF 35/41 reads (85%) | called by muse, mutect2, varscan2
- GEM | c.855C>A p.L285= | Silent (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- GJB7 | c.216C>G p.S72= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2823G>A p.A941= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs776500777; called by muse, mutect2, varscan2
- LAMA5 | c.6546C>T p.G2182= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs748553410; called by muse, mutect2, varscan2
- MSR1 | c.240G>A p.T80= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs749203568, COSV50521510; called by muse, mutect2, varscan2
- OCA2 | c.666C>T p.H222= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs751309779, COSV62351426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKN2 | c.1011C>T p.G337= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- RNF138 | c.648A>G p.Q216= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs773379320; called by muse, mutect2, varscan2
- SLC2A6 | c.720G>A p.T240= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs373828869; called by muse, mutect2, varscan2
